FM case AD1086 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mucoepidermoid Neoplasms; Primary site: Other and unspecified major salivary glands.
https://portal.gdc.cancer.gov/cases/4e93d9ec-3714-4f53-8216-a7b5361b5c5e

Female, 44.6 years: Mucoepidermoid carcinoma (ICD-O-3 8430/3) of the major salivary gland; specimen biopsied or resected from the pleura. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
